Somatic mutation profile of tumor specimen TCGA-F1-6875-01A (aliquot TCGA-F1-6875-01A-11D-2053-08) from TCGA case TCGA-F1-6875, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 80.0 years (29,209 days).
Specimen TCGA-F1-6875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d10b95be-54f0-4f6e-bcc3-590efb8d7d64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F1-6875-11A (Solid Tissue Normal), aliquot TCGA-F1-6875-11A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30317e2e-771c-4b62-b81b-9c013e3947c9

The open-access MAF lists 90 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 21, Nonsense Mutation 4, Splice Site 2, Splice Region 1, 3'UTR 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 38/49 reads (78%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+2T>G p.X261_splice | Splice Site (SNP) | VAF 35/43 reads (81%) | hotspot (GDC flag); catalogued as rs876659076, COSV52817854, COSV52933377, COSV53031948; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 95/114 reads (83%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs372629661; called by muse, mutect2, varscan2
- ACAN | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs62640041, COSV61357144; called by muse, mutect2, varscan2
- ACOT9 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 55/59 reads (93%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60537095; called by muse, mutect2, varscan2
- ADAM28 | c.895A>C p.T299P | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.602); catalogued as COSV56098664; called by muse, mutect2, varscan2
- ARFGAP2 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 171/192 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139591977; called by muse, mutect2, varscan2
- ARMH4 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV50762515; called by muse, mutect2, varscan2
- ATAD3C | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.25); catalogued as COSV58019706; called by muse, mutect2, varscan2
- BBS4 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as rs754792792, COSV51436976, COSV99166501; called by muse, mutect2, varscan2
- BOD1L1 | c.5291A>G p.D1764G | Missense Mutation (SNP) | VAF 151/324 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs151182576; called by muse, mutect2, varscan2
- CAMK1 | c.429G>A p.K143= | Splice Region (SNP) | VAF 24/54 reads (44%) | catalogued as rs757326779, COSV56537948; called by muse, mutect2, varscan2
- CENATAC | c.899T>C p.F300S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57722326; called by muse, mutect2, varscan2
- CHD5 | c.4634C>T p.S1545L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs201559496, COSV52409942; called by muse, mutect2, varscan2
- CLIP1 | c.4147G>A p.D1383N (on ENST00000620786 / NM_001247997.1; = p.D1372N on NM_002956.2) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV56798847; called by muse, mutect2, varscan2
- CSMD3 | c.7489A>G p.T2497A (on ENST00000297405 / NM_001363185.1; = p.T2393A on NM_052900.3) | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as rs746979067, COSV52126855; called by muse, mutect2, varscan2
- CXCR2 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59280014; called by muse, mutect2, varscan2
- DLG1 | c.2519A>G p.E840G (on ENST00000419354 / NM_001290983.1; = p.E862G on NM_004087.2) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV58379205; called by muse, mutect2, varscan2
- DMXL2 | c.8225C>G p.S2742C | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51842332; called by muse, mutect2, varscan2
- DNAAF5 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 94/163 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs746765259, COSV52414987; called by muse, mutect2, varscan2
- EPHA3 | c.1968A>C p.K656N | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60697791; called by muse, mutect2, varscan2
- FAM47A | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1334539034, COSV60494973; called by muse, varscan2
- FCGR3B | c.197T>A p.L66H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.103); catalogued as rs761007181, COSV99670834; called by muse, mutect2, varscan2
- GALNT16 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61884983; called by muse, mutect2, varscan2
- GLB1L2 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs539605151, COSV60277866; called by muse, varscan2
- GPATCH4 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV58039268; called by muse, mutect2, varscan2
- IL21R | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV61969120; called by muse, mutect2, varscan2
- IL36A | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs539941311, COSV52082746; called by muse, mutect2, varscan2
- KCNJ11 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479483693, CM051093, CM104936, COSV60594280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV57824989; called by muse, mutect2, varscan2
- LRP12 | c.753G>C p.E251D | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52626882; called by muse, mutect2, varscan2
- MADD | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60621434; called by muse, mutect2, varscan2
- MAGEB6 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV66872016; called by muse, mutect2, varscan2
- MDGA1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1197290238, COSV51792850; called by muse, mutect2, varscan2
- MNDA | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV63739813, COSV63740186, COSV63741376; called by muse, mutect2, varscan2
- MUC3A | c.7628C>G p.T2543S | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT tolerated, low confidence (0.05); catalogued as rs1295544431, COSV60222454; called by muse, mutect2, varscan2
- MUC3A | c.9011A>G p.Y3004C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs762561742; called by muse, mutect2, varscan2
- MYO18B | c.2066C>A p.S689* | Nonsense Mutation (SNP) | VAF 92/143 reads (64%) | catalogued as COSV59128439; called by muse, mutect2, varscan2
- NIN | c.505T>G p.L169V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV55383249; called by muse, mutect2, varscan2
- NLRP10 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1332579904, COSV100149551, COSV60779160; called by muse, mutect2, varscan2
- NTM | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV66175345; called by muse, mutect2, varscan2
- OR4N2 | c.709A>T p.M237L | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60050473; called by muse, mutect2, varscan2
- OR6K2 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV62743233; called by muse, mutect2, varscan2
- PAQR9 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.835); catalogued as COSV61417748; called by muse, mutect2, varscan2
- PCDHB10 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs1333580766, COSV53376430; called by muse, mutect2, varscan2
- PITPNM3 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV52593704; called by muse, mutect2, varscan2
- PKD1L1 | c.2065-1G>A p.X689_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV56960433, COSV56973536; called by muse, mutect2, varscan2
- PLOD2 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs368177696; called by muse, mutect2, varscan2
- POLM | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs769788085, COSV54241712; called by muse, mutect2, varscan2
- PPFIA3 | c.2704G>T p.V902F | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV61950269; called by muse, mutect2
- PTGES3L-AARSD1 | c.949C>T p.R317W (on ENST00000421990 / NM_001136042.2; = p.R299W on NM_025267.3) | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs574315993, COSV64182118; called by muse, mutect2, varscan2
- RNF38 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52393423; called by muse, mutect2
- SP140 | c.1675T>C p.F559L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100613981, COSV59447452; called by muse, mutect2, varscan2
- SYVN1 | c.1483C>A p.H495N (on ENST00000377190 / NM_172230.3; = p.H494N on NM_032431.3) | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV53694948; called by muse, mutect2, varscan2
- TARS1 | c.461G>A p.W154* | Nonsense Mutation (SNP) | VAF 44/81 reads (54%) | catalogued as COSV54307926; called by muse, mutect2, varscan2
- TAS2R5 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 92/151 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1416264820, COSV56094576; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1667T>C p.V556A | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV51510500; called by muse, mutect2, varscan2
- TLR4 | c.628C>A p.L210M (on ENST00000355622 / NM_138554.5; = p.L170M on NM_003266.4) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV62922683; called by muse, mutect2, varscan2
- TMEM47 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV52063962; called by muse, mutect2, varscan2
- XRCC5 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV67535199; called by muse, mutect2, varscan2
- ZMYND12 | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.675); catalogued as rs772839967, COSV65333547; called by muse, mutect2, varscan2
- ZNF438 | c.1951C>G p.R651G | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59193031; called by muse, mutect2, varscan2
- ZNF462 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs755534398, COSV52932005; called by muse, mutect2, varscan2
- ZNF530 | c.1577A>C p.K526T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60531078; called by muse, mutect2, varscan2
- CCL4L2 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- HECW1 | c.3467del p.G1156Vfs*18 | Frame Shift Del (DEL) | VAF 25/222 reads (11%) | called by mutect2, pindel, varscan2
- RIPOR3 | c.2440C>A p.L814I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACTA2 | c.783G>A p.E261= | Silent (SNP) | VAF 42/156 reads (27%) | catalogued as COSV56515876; called by muse, mutect2, varscan2
- ADD2 | c.1044C>T p.A348= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as rs376528363; called by muse, mutect2, varscan2
- APBA2 | c.168C>T p.P56= | Silent (SNP) | VAF 46/52 reads (88%) | catalogued as rs367887200, COSV68789165; called by muse, mutect2, varscan2
- CCDC116 | c.1779T>C p.D593= | Silent (SNP) | VAF 41/58 reads (71%) | catalogued as COSV53039680; called by muse, mutect2, varscan2
- CDH8 | c.1371A>G p.E457= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs973891787, COSV54854213; called by muse, mutect2, varscan2
- CES5A | c.1506T>C p.N502= (on ENST00000290567 / NM_001143685.2; = p.N452= on NM_145024.3) | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as rs1438714217, COSV51864711; called by muse, mutect2
- CLCNKB | c.402C>T p.V134= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as COSV65159975; called by muse, mutect2, varscan2
- DGKZ | c.3042G>A p.T1014= (on ENST00000454345 / NM_001105540.2; = p.T826= on NM_003646.4) | Silent (SNP) | VAF 16/17 reads (94%) | catalogued as rs142962841; called by muse, mutect2, varscan2
- DPYS | c.303C>T p.F101= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs141057778; called by muse, mutect2, varscan2
- EPHA8 | c.897C>T p.S299= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs372203085, COSV51306118; called by muse, mutect2, varscan2
- FAM13A | c.975A>G p.A325= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV51998867; called by muse, mutect2, varscan2
- FNBP4 | c.1257A>C p.R419= | Silent (SNP) | VAF 45/49 reads (92%) | catalogued as COSV55447058; called by muse, mutect2, varscan2
- GOT2 | c.585G>A p.V195= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV55331074; called by muse, mutect2, varscan2
- GRM1 | c.921C>T p.G307= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs150520977; called by muse, mutect2, varscan2
- LYPD1 | c.363C>T p.L121= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as rs764799579, COSV61415976; called by muse, mutect2, varscan2
- MYB | c.1071G>A p.L357= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV57196769; called by muse, mutect2, varscan2
- PFKFB1 | c.1386A>G p.E462= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV51499077; called by muse, mutect2, varscan2
- PLEKHG3 | c.1359G>A p.P453= (on ENST00000394691; = p.P509= on NM_001308147.2) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs944758661, COSV55978270; called by muse, mutect2, varscan2
- STT3B | c.1252C>T p.L418= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV55501684; called by muse, mutect2, varscan2
- TMC6 | c.573C>G p.G191= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as rs747205872, COSV59808287; called by muse, mutect2, varscan2
- ZNF536 | c.3753G>A p.P1251= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs573555056, COSV62820378; called by muse, mutect2, varscan2
- DPF3 | c.871+3049G>A | Intron (SNP) | VAF 11/28 reads (39%) | catalogued as rs955224884; called by muse, mutect2, varscan2
- LARS2 | c.*470C>T | 3'UTR (SNP) | VAF 16/44 reads (36%) | catalogued as rs779962003, COSV55525256; called by muse, mutect2, varscan2
